Somatic mutation profile of tumor specimen TCGA-06-0140-01A (aliquot TCGA-06-0140-01A-01D-1490-08) from TCGA case TCGA-06-0140, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 86.4 years (31,566 days).
Specimen TCGA-06-0140-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75f54224-753e-440f-b652-bb08354ff72a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0140-10A (Blood Derived Normal), aliquot TCGA-06-0140-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c47801c6-baf7-47ef-91eb-7ed3e0c45ccb

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 30, Silent 7, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6688C>T p.L2230F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV64673216; called by muse, mutect2, varscan2
- ADAMTS18 | c.2247G>C p.K749N | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV51407176; called by muse, mutect2, varscan2
- ADM2 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV53312803; called by muse, mutect2, varscan2
- AKAP4 | c.2119C>T p.L707F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557203788, COSV62074313; called by muse, mutect2, varscan2
- ATP10A | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs777738173, COSV63516773; called by muse, mutect2, varscan2
- CHST6 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1403332336, COSV59999976; called by muse, mutect2, varscan2
- CYP26B1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.771); catalogued as rs534997827, COSV50011641; called by muse, mutect2, varscan2
- ECT2L | c.2321G>A p.C774Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758762878, COSV62884177; called by muse, mutect2, varscan2
- ELN | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV52709786; called by muse, mutect2, varscan2
- GTF2IRD1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs139144176, COSV56086308; called by muse, mutect2, varscan2
- HECTD4 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as COSV101106878, COSV66391214; called by muse, mutect2, varscan2
- HTR3A | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs528104456, COSV55468629; called by muse, mutect2, varscan2
- IL7R | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV57408234; called by muse, mutect2, varscan2
- KIFC3 | c.2089A>G p.I697V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV65550092; called by muse, mutect2, varscan2
- MS4A7 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1326492620, COSV55729369, COSV55729706; called by muse, mutect2, varscan2
- NBAS | c.4001G>A p.R1334H | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140188229; called by muse, mutect2, varscan2
- OR51A2 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV66748308; called by muse, mutect2, varscan2
- PIGR | c.1055T>A p.I352N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62903838; called by muse, mutect2, varscan2
- PLA1A | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV56331590; called by muse, mutect2, varscan2
- PRPF40A | c.2620G>A p.D874N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV68357203; called by muse, mutect2, varscan2
- PTPRT | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.527); catalogued as rs776769442, COSV61975097; called by muse, mutect2, varscan2
- RB1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 58/136 reads (43%) | catalogued as CM092254, COSV57305848; called by muse, mutect2, varscan2
- REPIN1 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV68292179; called by muse, mutect2, varscan2
- SCG2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV59539824; called by muse, mutect2, varscan2
- ST6GAL2 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 41/226 reads (18%) | PolyPhen benign (0.01); catalogued as rs377166692, COSV64530947; called by muse, mutect2, varscan2
- STKLD1 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs587748084, COSV64312508; called by muse, mutect2, varscan2
- TRIM2 | c.649G>A p.V217M (on ENST00000437508; = p.V244M on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs766381258, COSV58633120; called by muse, mutect2, varscan2
- UTP15 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57140813; called by muse, mutect2, varscan2
- VWCE | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV57112186; called by muse, mutect2
- WNK2 | c.4678G>A p.V1560I (on ENST00000297954 / NM_001282394.1; = p.V1523I on NM_006648.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs371709081; called by muse, mutect2, varscan2
- ZNF71 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV60147691; called by muse, mutect2, varscan2
- AZGP1 | c.703del p.I235Lfs*101 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- BCOR | c.2414_2415insGTCTG p.Y805* | Nonsense Mutation (INS) | VAF 52/118 reads (44%) | called by mutect2, varscan2
- CILP2 | c.2799G>A p.P933= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1007581203, COSV52274650; called by mutect2, varscan2
- CLRN3 | c.273G>A p.S91= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs777602428, COSV64098531; called by muse, mutect2, varscan2
- GRIA1 | c.2703G>A p.L901= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV53600925; called by muse, mutect2, varscan2
- IRF4 | c.738G>A p.A246= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs144395675; called by muse, mutect2, varscan2
- KRT16 | c.909C>T p.D303= | Silent (SNP) | VAF 58/270 reads (21%) | catalogued as rs748022914, COSV56967844; ClinVar: likely benign; called by muse, mutect2, varscan2
- LMTK3 | c.264G>A p.A88= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1349901718, COSV54311884; called by muse, mutect2, varscan2
- MRPL3 | c.639A>G p.K213= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV53914135; called by muse, mutect2, varscan2
